Gene-level copy-number profile of tumor specimen TCGA-XX-A899-01A from TCGA case TCGA-XX-A899, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 46.6 years (17,022 days).
Specimen TCGA-XX-A899-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.31fad9a6-80ba-4ed8-862a-d8e17816c645.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XX-A899-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cf0601ad-0d81-4321-8b8e-a305a3c51687

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,222; copy number 2: 48,506; copy number 3: 4,502; copy number 4: 104; copy number 6: 49; copy number 9: 22; copy number 10: 109; copy number 11: 22; copy number 14: 142; copy number 19: 15; copy number 22: 94; copy number 23: 3; copy number 24: 28.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XX-A899-01A-11D-A36I-01): tumor purity 0.38, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 484 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:37,326,575–43,674,591, 169 genes, copy number 10–14 (broad region; genes not listed).
- chr11:68,980,021–70,436,584, 47 genes, copy number 9–24: MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:70,477,277–70,635,658, 3 genes, copy number 9: AP001271.1, AP001271.2, SHANK2-AS1.
- chr11:73,307,235–77,126,155, 130 genes, copy number 14–22 (within-gene range 2–22) (broad region; genes not listed).
- chr11:77,322,017–79,612,300, 46 genes, copy number 22 (within-gene range 2–22): PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1, RNU6-311P, COPS8P3, TENM4, AP002768.1, AP002957.1, AP001547.1, MIR708, MIR5579, AP001978.1.
- chr11:80,321,620–80,653,988, 3 genes, copy number 23: AP006295.1, RNU6-544P, ARL6IP1P3.
- chr11:101,029,624–102,378,670, 22 genes, copy number 11: PGR, PGR-AS1, AP001533.1, TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2.
- chr11:106,075,501–107,457,844, 15 genes, copy number 19 (within-gene range 1–19): AASDHPPT, AP001001.1, AP001001.2, LINC02719, AP002001.3, AP002001.1, AP002001.2, AP003173.1, GUCY1A2, AP001282.2, AP001282.1, ASS1P13, AP000766.1, CWF19L2, SMARCE1P1.
- chr12:69,608,564–70,920,738, 21 genes, copy number 6 (within-gene range 4–6): LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA.
- chr12:71,839,707–71,927,248, 1 gene, copy number 6 (within-gene range 3–6): TBC1D15.
- chr12:71,938,845–75,044,793, 27 genes, copy number 6: TPH2, AC090109.1, TRHDE, TRHDE-AS1, H3P35, CHCHD3P2, AC133480.1, AC090503.2, LINC02444, AC090503.1, AC087879.1, RNU6-1012P, LINC02445, U8, LINC02882, AC136188.1, LINC02394, AC090502.3, AC090502.2, AC090502.1, VENTXP3, ATXN7L3B, AC025257.1, AC123904.2, AC123904.1, AC123904.3, AC073525.1.

Autosomal genes at a single copy (total copy number 1): 6,144. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
